Somatic mutation profile of tumor specimen TCGA-BJ-A0ZH-01A (aliquot TCGA-BJ-A0ZH-01A-11D-A10S-08) from TCGA case TCGA-BJ-A0ZH, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 52.3 years (19,114 days).
Specimen TCGA-BJ-A0ZH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a390c6e0-a709-4d0f-bbc7-d5d78eb27dbd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A0ZH-10A (Blood Derived Normal), aliquot TCGA-BJ-A0ZH-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6694cbb4-d2f0-4e6c-b9a6-529d90b0e6cc

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, RNA 1, Translation Start Site 1, Intron 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRCA2 | c.8794C>T p.H2932Y | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV66450087; called by muse, mutect2, varscan2
- CFAP45 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV63650830; called by muse, mutect2, varscan2
- CYP2E1 | c.549C>G p.I183M | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53315115; called by muse, mutect2
- ERO1A | c.227A>G p.Y76C | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67471986; called by muse, mutect2
- GPRASP1 | c.1960A>T p.M654L | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV64356361; called by muse, mutect2
- LRRC4C | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as rs1399283486, COSV53436333; called by muse, mutect2, varscan2
- LUC7L3 | c.884C>A p.S295* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV53589206; called by muse, mutect2, varscan2
- OR13F1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58252544; called by muse, mutect2
- PIGO | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV53055132, COSV99956540; called by muse, mutect2, varscan2
- PTPRO | c.127T>C p.S43P | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.723); catalogued as COSV55520908; called by muse, mutect2, varscan2
- SETD2 | c.3414G>C p.E1138D | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV100338616, COSV57449014; called by muse, mutect2
- TTC8 | c.707C>G p.S236C (on ENST00000338104 / NM_001288781.1; = p.S220C on NM_144596.4) | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV57630265; called by muse, mutect2, varscan2
- ZNF28 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 16/529 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100354464, COSV60425071; called by muse, mutect2
- MUC16 | c.38907C>G p.V12969= | Silent (SNP) | VAF 12/334 reads (4%) | catalogued as COSV67489066; called by muse, mutect2
- CTSL3P | n.626G>A | RNA (SNP) | VAF 13/123 reads (11%) | called by muse, mutect2, varscan2
- UNG | c.133-31C>G | Intron (SNP) | VAF 5/94 reads (5%) | catalogued as COSV54358687; called by muse, mutect2
